Gene-level copy-number profile of tumor specimen TCGA-DK-A1A3-01A from TCGA case TCGA-DK-A1A3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,235 days).
Specimen TCGA-DK-A1A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a9479ff0-0428-4e68-97fd-928aad3cb6f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1A3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdc4b367-0c31-43ea-a971-604380d8c451

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 292; copy number 2: 16,374; copy number 3: 19,979; copy number 4: 15,403; copy number 5: 6,866; copy number 6: 306; copy number 7: 229; copy number 8: 30; copy number 10: 109; copy number 11: 148; copy number 15: 21; copy number 16: 38; copy number 18: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1A3-01A-11D-A13V-01): tumor purity 0.43, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 589 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,026,738–8,122,702, 2 genes, copy number 10: AL034417.2, AL034417.1.
- chr1:18,839,599–19,075,511, 6 genes, copy number 7: TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2, AL137127.1.
- chr1:20,186,096–27,234,352, 246 genes, copy number 7–11 (broad region; genes not listed).
- chr1:39,081,316–40,474,059, 50 genes, copy number 10 (within-gene range 3–10): MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4.
- chr5:51,275,253–51,665,048, 7 genes, copy number 7: AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr6:106,695,535–107,115,515, 7 genes, copy number 15: LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3.
- chr15:47,603,880–48,663,056, 20 genes, copy number 7: AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4.
- chr15:67,819,704–68,432,163, 14 genes, copy number 18: SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11.
- chr16:46,469,341–48,620,148, 58 genes, copy number 11 (within-gene range 3–11): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44.
- chr19:28,294,093–33,361,448, 111 genes, copy number 7–15 (broad region; genes not listed).
- chr19:36,682,636–38,383,824, 68 genes, copy number 8–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
